Surgical pathology report (de-identified scan), TCGA case TCGA-FF-A7CR, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-A7CR-01A (Primary Tumor).

Patient Results

Requested By:

	Histopathology Report	Biopsy No:	Corrected
Received Date/Time		Final	
Reporting Information	Date/Time : Histopathologist : Laboratory :	Final	Updated
Consultant-In-Charge		Final	
Submitting Physician		Final	
Histopathology Report		Final	Updated

ADDENDUM

ADDENDUM TO HISTOPATHOLOGY REPORT

Immunohistochemistry shows a population of CD20+ large B-cells, dispersed and coalescing amidst a background of small B-lymphocytes, with both components highlighted by B-cell-specific activator protein shown on double labelling to aberrantly coexpress CD5 (which highlights an occasional large cell in mitosis on the single stain) in excess of the amount accounted for by background, small-to-medium sized, CD2/3/7+ T-lymphocytes, albeit plentiful, consistent with a brisk, reactive accompaniment, an impression further supported by an excess of the CD8 over the CD4 subset, the latter upon subtraction double immunolabelling for CD163(+) histiocytes. The overall cell proliferation fraction is 20-30% on Ki-67 immunolabelling. Immunostaining for cyclin D1 is negative within the lymphoid population, highlighting only physiological expression in scattered histiocytic and activated endothelial nuclei, ruling out mantle cell lymphoma and its variants. CD138-positivity is restricted to mature plasma cells with a kappa:lambda ratio ranging between 3:2 to 2:1 on mRNA in situ hybridisation (ISH), also consistent with a reactive accompaniment, and negating plasmablastic lymphoma in conjunction with negativity for both CD30 (which is seen only as physiological coexpression in a minor subset of plasma cells) as well as for EBV-Encoded RNA (EBER) on ISH. CD21-immunoreactive follicular dendritic meshworks are not identified, and CD10 positivity appears to reflect only physiological expression in scattered stromal cells and is negative in the lymphoid population, while CD20(+) large B-cells demonstrably coexpress MUM.1 on double immunolabelling, consistent with an "activated" state congruous with that of diffuse large B-cell lymphoma (DLBCL).

DIAGNOSIS

LEFT NECK LYMPH NODE; INCISIONAL BIOPSIES: DIFFUSE AGGRESSIVE LYMPHOMA. PENDING WORKUP.

Pathologist :

ICD-O-3
Lymphoma, diffuse large
B cell 9680/3
Site Cervical lymph node
C77.0
JG 8/26/13

Case (Initials)	QUALIFIED	UNQUALIFIED

Source: NCI Genomic Data Commons file f9ce3724-463d-446c-8477-bd941c81d693 (TCGA-FF-A7CR.C522C0BD-7968-48C0-8E96-6143740993E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).